TCGA case TCGA-DX-A6BG — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/969954a8-7f15-4052-9e6a-c5956115f3ad

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Alive.

Diagnoses (4)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 51.1 years (18,682 days); Year of diagnosis: 2012; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 9.5; Tumor width measurement: 7.9.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 5.1; Tumor length measurement: 6; Tumor width measurement: 5.8.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 7.3; Tumor length measurement: 10.8; Tumor width measurement: 7.6.
   Pathology details: Measurement type: Pathologic; Tumor burden: 16.8.
2. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma). Age at diagnosis: 51.6 years (18,831 days); Days to diagnosis: 149 days; Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 18.7; Tumor length measurement: 27.5; Tumor width measurement: 26.5.
3. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Retroperitoneum. Age at diagnosis: 51.6 years (18,831 days); Days to diagnosis: 149 days; Prior treatment: Yes; Tumor focality: Unifocal.
4. Metastasis of diagnosis 1 (Dedifferentiated liposarcoma), site: Peritoneum, NOS. Age at diagnosis: 52.6 years (19,200 days); Days to diagnosis: 518 days (1.4 years); Prior treatment: Yes.

Follow-up (6 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 2.
- Day 149 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 149 days; Discontiguous lesion count: 2.
- Days to follow up: 224 days; Disease response: With Tumor.
- Day 518 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Peritoneum, NOS; Days to progression: 518 days (1.4 years).
- Days to follow up: 541 days (1.5 years); Disease response: With Tumor.
- Days to follow up: 1,121 days (3.1 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A6BG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 670 mg.
  Slide TCGA-DX-A6BG-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A6BG-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A6BG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology: Margin status: Negative; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: Yes; Discontinuous lesions count: 2; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: No; Well diff liposarc prior diagnosis indicator: No.
- Primary pathology, Tumor sizes, Tumor size 2: Lesion pathologic length: 6.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 161; Days from index date to pharmaceutical treatment ended: 191; Pharmaceutical therapy drug name: PD 0332991; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 198; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: Yes.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 198; Pharmaceutical therapy drug name: Docetaxel; Pharmaceutical treatment ongoing indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,121 days; disease-specific survival: no event (censored), 1,121 days; disease-free interval: event (new tumor event after initially disease-free), 149 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 149 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A6BG-01A-11D-A306-01): tumor purity 0.25, ploidy 2.13, whole-genome doublings 0.
